Somatic mutation profile of tumor specimen TCGA-EE-A20B-06A (aliquot TCGA-EE-A20B-06A-11D-A196-08) from TCGA case TCGA-EE-A20B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.1 years (26,683 days).
Specimen TCGA-EE-A20B-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd3adc1-55a8-4951-913e-75c495d7a4cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A20B-10A (Blood Derived Normal), aliquot TCGA-EE-A20B-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/527b8c0b-9df5-46fa-abaa-fe5e7800ab9b

The open-access MAF lists 215 somatic variants for this specimen: 151 protein-altering or splice-affecting, 59 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 59, Splice Site 7, Nonsense Mutation 4, Splice Region 2, Intron 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8170C>T p.P2724S | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.601); catalogued as rs1085307904, COSV57315497; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.520T>A p.S174T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV59606732; called by muse, mutect2, varscan2
- ACTL6B | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV50514691; called by muse, mutect2, varscan2
- ADAM18 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV55846857; called by muse, mutect2, varscan2
- ADGRG4 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs143735478, COSV54953456; called by muse, mutect2, varscan2
- ADGRV1 | c.4580T>C p.I1527T | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV67984318; called by muse, mutect2, varscan2
- AKNAD1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62198016; called by muse, mutect2, varscan2
- AP4E1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV55916742, COSV99956145; called by muse, mutect2, varscan2
- ATG7 | c.529-2A>T p.X177_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV61612271; called by muse, mutect2, varscan2
- ATP2A3 | c.3068+7C>T | Splice Region (SNP) | VAF 22/57 reads (39%) | catalogued as COSV59228693; called by muse, mutect2, varscan2
- B3GALNT2 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV58356281; called by muse, mutect2, varscan2
- BCL11A | c.1190C>T p.S397L (on ENST00000335712 / NM_001365609.1; = p.S431L on NM_018014.4) | Missense Mutation (SNP) | VAF 189/477 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs138166869, COSV59625097; called by muse, mutect2, varscan2
- BRSK2 | c.1439A>G p.N480S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as COSV57542809; called by muse, mutect2, varscan2
- C12orf40 | c.1636A>G p.K546E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61131822; called by muse, mutect2, varscan2
- CACNA1S | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62939052; called by muse, mutect2, varscan2
- CACNA2D2 | c.2555C>T p.A852V (on ENST00000479441 / NM_001174051.3; = p.A845V on NM_006030.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1298263050, COSV56563030; called by muse, mutect2, varscan2
- CDC20B | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV57051927; called by muse, mutect2, varscan2
- CDH9 | c.1000-1G>A p.X334_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV50276196, COSV50541880, COSV99143658; called by muse, mutect2, varscan2
- CDH9 | c.1000-2A>T p.X334_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99143628; called by muse, mutect2, varscan2
- CEACAM20 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374407949; called by muse, mutect2, varscan2
- CHD8 | c.3209C>T p.S1070F (on ENST00000646647 / NM_001170629.2; = p.S791F on NM_020920.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1172358575, COSV67870405; called by muse, mutect2, varscan2
- CNOT4 | c.940C>T p.P314S (on ENST00000315544 / NM_001190848.1; = p.P311S on NM_013316.4) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs546146099, COSV59652162; called by muse, mutect2, varscan2
- COL1A2 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51957336; called by muse, mutect2, varscan2
- COL25A1 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV67649680; called by muse, mutect2, varscan2
- COL5A3 | c.3127-1G>A p.X1043_splice | Splice Site (SNP) | VAF 33/82 reads (40%) | catalogued as COSV53410089; called by muse, mutect2, varscan2
- CSF2RB | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV53257286; called by muse, mutect2, varscan2
- CSMD1 | c.7865C>T p.S2622L (on ENST00000520002; = p.S2621L on NM_033225.6) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377667100, COSV59317265; called by muse, mutect2, varscan2
- CSMD2 | c.10361G>A p.R3454Q | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs1431737649, COSV53907888, COSV99591312; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DDX3X | c.1144G>A p.A382T (on ENST00000399959; = p.A383T on NM_001356.5) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67863497, COSV67863841; called by muse, mutect2, varscan2
- DDX42 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); catalogued as COSV63790044; called by muse, mutect2, varscan2
- DIRAS2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV65370078; called by muse, mutect2, varscan2
- DMBX1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV63601959; called by muse, mutect2, varscan2
- DNAH5 | c.10667C>T p.P3556L | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1179894393, COSV54205876; called by muse, mutect2, varscan2
- DNAH7 | c.3893C>T p.S1298F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56762783; called by muse, mutect2, varscan2
- DNMT1 | c.3271G>T p.A1091S | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV61579053; called by muse, mutect2, varscan2
- DOK6 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV66930323; called by muse, mutect2, varscan2
- DSC1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57145311; called by muse, mutect2, varscan2
- EPHA8 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV51267321; called by muse, mutect2, varscan2
- EZH1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV70549267; called by muse, mutect2, varscan2
- FAM227B | c.875-1G>A p.X292_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV54810253; called by muse, mutect2, varscan2
- FAM83H | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66353816; called by muse, mutect2, varscan2
- FLNA | c.6583A>G p.N2195D (on ENST00000369850 / NM_001110556.2; = p.N2187D on NM_001456.3) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61042191; called by muse, mutect2, varscan2
- FSHR | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58622731; called by muse, mutect2, varscan2
- GABRE | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV100944205, COSV64819519; called by muse, mutect2, varscan2
- GINM1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV66389714; called by muse, mutect2, varscan2
- GRAMD1A | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373777473, COSV58766805; called by muse, mutect2, varscan2
- GRIA2 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.484); catalogued as COSV99644032; called by muse, mutect2, varscan2
- GUCY1A2 | c.1219A>C p.K407Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56485300; called by muse, mutect2, varscan2
- GUK1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs1186749993, COSV57155945; called by muse, mutect2, varscan2
- HDAC9 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.297); catalogued as COSV67766536, COSV67772335; called by muse, mutect2, varscan2
- HSH2D | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV53737871; called by muse, mutect2, varscan2
- HYDIN | c.8357G>A p.R2786Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs1211165728, COSV99992604; called by mutect2, varscan2
- IRF4 | c.779A>C p.E260A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.19); catalogued as COSV66705111; called by muse, mutect2, varscan2
- IRS1 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59335968; called by muse, mutect2, varscan2
- ITGA11 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59876981; called by muse, mutect2, varscan2
- ITIH2 | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV64432971; called by muse, mutect2, varscan2
- KANK2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs764930410, COSV62007797; called by muse, mutect2, varscan2
- KIF13B | c.4244C>A p.S1415Y | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.52); catalogued as COSV68094212; called by muse, mutect2, varscan2
- KLHL40 | c.1755G>A p.R585= | Splice Region (SNP) | VAF 37/92 reads (40%) | catalogued as rs1198699463, COSV55134300; called by muse, mutect2, varscan2
- LAMC2 | c.3278T>C p.V1093A | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV51455100; called by muse, mutect2, varscan2
- LIPF | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138641581; called by muse, mutect2, varscan2
- LMOD3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV70456016; called by muse, mutect2, varscan2
- LRRC40 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63942196; called by muse, mutect2, varscan2
- MAP1A | c.1982T>C p.M661T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as COSV55808228; called by muse, mutect2, varscan2
- MAP3K4 | c.3518G>A p.G1173E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV62333043; called by muse, mutect2, varscan2
- MARCO | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59053994; called by muse, varscan2
- MARK1 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 178/337 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs748779509, COSV65067034; called by muse, mutect2, varscan2
- MECOM | c.1756G>A p.D586N (on ENST00000468789 / NM_001105078.4; = p.D774N on NM_004991.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52963760; called by muse, mutect2, varscan2
- MPDU1 | c.682G>C p.A228P | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as COSV100002049; called by muse, mutect2, varscan2
- MPZL2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV54048746; called by muse, mutect2, varscan2
- MTOR | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63870813; called by muse, mutect2, varscan2
- MUC16 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as rs754368524, COSV67462702; called by muse, mutect2, varscan2
- MUC16 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as COSV67459615, COSV67462707; called by muse, mutect2
- MYO15A | c.10448G>A p.G3483E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007276558, COSV52755973, COSV99233263; called by muse, mutect2, varscan2
- MYO1E | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as rs761790029, COSV55686425; called by muse, mutect2, varscan2
- MYO3B | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774343513, COSV100509961; called by muse, mutect2, varscan2
- MYOM2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1489890751, COSV100036363; called by muse, mutect2, varscan2
- NAA80 | c.307C>T p.L103F (on ENST00000417393 / NM_001200018.2; = p.L125F on NM_012191.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs782442485, COSV99807608; called by muse, mutect2, varscan2
- NCAM1 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57515615; called by muse, mutect2, varscan2
- NYAP1 | c.1820A>T p.H607L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV55718573; called by muse, mutect2, varscan2
- OLFM3 | c.273A>C p.E91D (on ENST00000338858 / NM_001288821.1; = p.E71D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV58798308; called by muse, mutect2, varscan2
- OPN3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1213209489, COSV59363910; called by muse, mutect2
- OR10R2 | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV63768787; called by muse, mutect2, varscan2
- OR14K1 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV51722434, COSV99315275; called by muse, mutect2, varscan2
- OR2G2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 128/232 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60740372; called by muse, mutect2, varscan2
- OR2T10 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57896714; called by muse, mutect2, varscan2
- OR3A1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60162992; called by muse, mutect2, varscan2
- OR4L1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1566538748, COSV59849670; called by muse, mutect2, varscan2
- OR5P2 | c.846C>A p.N282K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1356994131, COSV61490465; called by muse, mutect2, varscan2
- OR8I2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100136020; called by muse, mutect2, varscan2
- OR8I2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1183467205, COSV56169870; called by muse, mutect2, varscan2
- PACS1 | c.932T>G p.V311G | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV57697480; called by muse, mutect2, varscan2
- PCDHGB3 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV53938558; called by muse, mutect2, varscan2
- PHLDB2 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV67309719; called by muse, mutect2, varscan2
- PHLPP2 | c.2618C>T p.S873F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1350690980, COSV62424295; called by muse, mutect2, varscan2
- PKP2 | c.2342C>G p.T781R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV50730055; called by muse, mutect2, varscan2
- PLEKHS1 | c.543G>A p.M181I (on ENST00000369310 / NM_182601.1; = p.M187I on NM_024889.5) | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1189003951, COSV63054852; called by muse, mutect2, varscan2
- PNLIPRP3 | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV65047851; called by muse, mutect2, varscan2
- POF1B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs769742545, COSV53130636; called by muse, mutect2, varscan2
- PPP4R4 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV58554203; called by muse, mutect2, varscan2
- PRDM9 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57002771, COSV57005738; called by muse, mutect2, varscan2
- RBM14 | c.1688_1689insT p.Q563Hfs*15 | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | catalogued as COSV100036667; called by pindel, varscan2
- RENBP | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as COSV64169750; called by muse, mutect2, varscan2
- RP9 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51806355, COSV51806690; called by muse, mutect2
- RYR2 | c.13039G>A p.E4347K | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as COSV63682793; called by muse, mutect2, varscan2
- SHROOM4 | c.4189G>A p.D1397N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1557247023, COSV56787794; called by muse, mutect2, varscan2
- SIGLEC6 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58433848; called by muse, mutect2, varscan2
- SIRPD | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV67546543; called by muse, mutect2, varscan2
- SLC14A2 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.925); catalogued as COSV54908605; called by muse, mutect2, varscan2
- SLC18A2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100041562; called by muse, mutect2, varscan2
- SLC18A2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs767337086, CM162397, COSV100041218, COSV53691108; called by muse, mutect2, varscan2
- SLC25A17 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs139416009, COSV54351169; called by muse, mutect2, varscan2
- SLC51A | c.929C>A p.T310N | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV53055989; called by muse, mutect2, varscan2
- SLC6A18 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs772068090, COSV57251018; called by muse, mutect2, varscan2
- SLIT2 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV56570327; called by muse, mutect2, varscan2
- SMC1B | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV62528358, COSV62529759; called by muse, mutect2, varscan2
- SMG5 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.877); catalogued as COSV100700762; called by muse, mutect2, varscan2
- SPAG17 | c.4763G>A p.G1588E | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs781388157, COSV60453609; called by muse, mutect2, varscan2
- SPATA7 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs267604078, COSV50415827; called by muse, mutect2, varscan2
- SPRYD3 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56853683; called by muse, mutect2, varscan2
- SPTA1 | c.5108C>A p.A1703D | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV63752396; called by muse, mutect2, varscan2
- STK33 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV59400439; called by muse, mutect2, varscan2
- SYNE2 | c.3457C>T p.Q1153* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV59949257, COSV59955505; called by muse, mutect2, varscan2
- TEP1 | c.3002G>A p.G1001E | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99402160; called by muse, mutect2, varscan2
- TEP1 | c.3001G>A p.G1001R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452155117, COSV99402162; called by muse, mutect2, varscan2
- THEM5 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.137); catalogued as COSV64312870; called by muse, mutect2, varscan2
- THOC2 | c.4217-1G>A p.X1406_splice | Splice Site (SNP) | VAF 56/198 reads (28%) | catalogued as COSV55545155; called by muse, mutect2, varscan2
- THRAP3 | c.1412G>A p.W471* | Nonsense Mutation (SNP) | VAF 28/109 reads (26%) | catalogued as COSV63567601; called by muse, mutect2, varscan2
- THSD7B | c.3595G>A p.E1199K (on ENST00000272643; = p.E1197K on NM_001316349.2) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763724242, COSV55705268; called by mutect2, varscan2
- TMEM132B | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs778222027, COSV54745792; called by muse, mutect2, varscan2
- TMTC2 | c.1375A>G p.T459A | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1011266798, COSV58267443; called by muse, mutect2, varscan2
- TNIK | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV52681081, COSV99456172; called by muse, mutect2, varscan2
- TNRC6C | c.4115C>T p.S1372F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV100050572, COSV56940369; called by muse, mutect2, varscan2
- TRPV5 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 86/110 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54685360; called by muse, mutect2, varscan2
- UGT2B4 | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1170050355, COSV59316895; called by muse, mutect2, varscan2
- USP17L2 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs770234887, COSV61555695; called by mutect2, varscan2
- WASHC4 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV59889372; called by muse, mutect2, varscan2
- WNK2 | c.3913G>A p.V1305I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1054249873, COSV52940192; called by muse, mutect2
- YEATS2 | c.1232T>C p.M411T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV59364949; called by muse, mutect2, varscan2
- ZNF335 | c.4003G>A p.D1335N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs748843555, COSV59817508; called by muse, mutect2, varscan2
- ZNF407 | c.445A>T p.T149S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55251189; called by muse, mutect2, varscan2
- ZNF683 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62874177; called by muse, mutect2, varscan2
- ZNF700 | c.895A>G p.S299G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV54312200; called by muse, mutect2, varscan2
- ZNF761 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV61888211; called by muse, mutect2, varscan2
- ZNF821 | c.832C>T p.R278C (on ENST00000425432 / NM_001376297.1; = p.R236C on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1226993135, COSV57987030; called by muse, mutect2, varscan2
- NAP1L3 | c.481del p.E161Nfs*28 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- POTEA | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEPTIN5 | c.320_327del p.V107Afs*25 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- ABCB5 | c.1935A>C p.S645= (on ENST00000404938 / NM_001163941.2; = p.S200= on NM_178559.6) | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV51708558; called by muse, mutect2, varscan2
- AP1M1 | c.609C>T p.F203= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV52226323; called by muse, mutect2, varscan2
- ARPP21 | c.1017G>A p.G339= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51796963; called by muse, mutect2, varscan2
- ATP7A | c.1221C>T p.S407= | Silent (SNP) | VAF 59/137 reads (43%) | catalogued as COSV58445696; called by muse, mutect2, varscan2
- BCOR | c.3402G>A p.R1134= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100654328, COSV60706150; called by muse, mutect2, varscan2
- CAPS2 | c.1254C>T p.I418= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV60825262; called by muse, mutect2, varscan2
- CCR7 | c.1056C>A p.L352= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV55849295; called by muse, mutect2, varscan2
- COL6A3 | c.6120G>A p.R2040= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs767129751, COSV55088027, COSV99796171; called by muse, mutect2, varscan2
- CRTC2 | c.1671G>A p.G557= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV57842554; called by muse, mutect2, varscan2
- CYP1A1 | c.1116C>T p.I372= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV65697058; called by muse, mutect2, varscan2
- CYP2C19 | c.513C>T p.G171= | Silent (SNP) | VAF 62/113 reads (55%) | catalogued as COSV64907652; called by muse, mutect2, varscan2
- DGKB | c.1719G>A p.E573= | Silent (SNP) | VAF 69/235 reads (29%) | catalogued as COSV51779584, COSV51831555; called by muse, mutect2, varscan2
- DMD | c.8988T>C p.N2996= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV58907649; called by muse, mutect2, varscan2
- DMRT1 | c.747G>A p.G249= | Silent (SNP) | VAF 53/76 reads (70%) | catalogued as COSV66519336; called by muse, mutect2, varscan2
- FAM111A | c.118C>T p.L40= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV64655293; called by muse, mutect2, varscan2
- FAM81A | c.111C>T p.I37= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV55677519; called by muse, mutect2, varscan2
- G6PC | c.556C>T p.L186= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV53830888; called by muse, mutect2, varscan2
- GRIA2 | c.966C>T p.S322= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV99644036; called by muse, mutect2, varscan2
- HSPA9 | c.261C>T p.T87= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV51864309; called by muse, mutect2, varscan2
- HYDIN | c.4224C>T p.I1408= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101142003; called by muse, mutect2, varscan2
- IGSF21 | c.378G>A p.R126= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV52132169; called by muse, mutect2
- ITIH3 | c.1305C>T p.F435= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV69648642; called by muse, varscan2
- KCNH7 | c.522C>T p.S174= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV59795212; called by muse, mutect2, varscan2
- KIF13A | c.5055C>T p.I1685= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs184937831, COSV52449442; called by muse, mutect2, varscan2
- KLHDC9 | c.450G>A p.R150= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV63509574; called by muse, mutect2
- LIMK1 | c.1587G>A p.K529= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV60281252; called by muse, mutect2, varscan2
- MRGPRX2 | c.627C>T p.I209= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs769886980, COSV61674138; called by muse, mutect2, varscan2
- OR6C68 | c.678C>T p.F226= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV65563241; called by muse, mutect2, varscan2
- OR8B4 | c.39C>T p.I13= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs151066825, COSV62069478; called by mutect2, varscan2
- OSBPL10 | c.1395C>T p.A465= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV67338799; called by muse, mutect2, varscan2
- PCDHGA2 | c.144C>T p.I48= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV53938543; called by muse, mutect2, varscan2
- PLCB4 | c.3438C>T p.F1146= | Silent (SNP) | VAF 30/45 reads (67%) | catalogued as COSV53800320; called by muse, mutect2, varscan2
- PRSS48 | c.276G>A p.R92= | Silent (SNP) | VAF 112/229 reads (49%) | catalogued as rs756886624, COSV71613779; called by muse, mutect2, varscan2
- PSD3 | c.414G>A p.L138= | Silent (SNP) | VAF 66/182 reads (36%) | catalogued as COSV58967755; called by muse, mutect2, varscan2
- PTPRU | c.3819C>T p.I1273= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs375146224; called by muse, mutect2, varscan2
- RNF145 | c.633A>G p.V211= (on ENST00000424310 / NM_001199383.2; = p.V239= on NM_144726.2) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV50866077; called by muse, mutect2, varscan2
- ROR2 | c.2091C>T p.S697= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV65218642; called by muse, mutect2, varscan2
- S100A7L2 | c.105G>A p.L35= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64195070; called by muse, mutect2, varscan2
- SAMD9 | c.2616C>T p.I872= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV66074847; called by muse, mutect2, varscan2
- SH3PXD2B | c.2151T>C p.D717= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV61126567; called by muse, mutect2, varscan2
- SIGLEC10 | c.858G>A p.L286= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59481195; called by muse, mutect2, varscan2
- SLC8A3 | c.2241C>T p.P747= (on ENST00000381269 / NM_183002.3; = p.P745= on NM_033262.4) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs760038494, COSV53688056, COSV53689021; called by muse, mutect2, varscan2
- SLC9A5 | c.1833G>A p.P611= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs377060606; called by muse, mutect2, varscan2
- SMG5 | c.1878G>A p.S626= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as rs752733587, COSV62433889; called by muse, mutect2, varscan2
- SPATA17 | c.585G>A p.K195= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV65121520; called by muse, mutect2, varscan2
- SPEG | c.3666C>T p.F1222= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56667931; called by muse, mutect2, varscan2
- SPHKAP | c.1362G>A p.Q454= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV100764693, COSV60877179; called by muse, mutect2, varscan2
- SPNS3 | c.1029C>T p.L343= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as rs781366952, COSV61069948; called by muse, mutect2, varscan2
- SV2A | c.174C>T p.F58= | Silent (SNP) | VAF 75/135 reads (56%) | catalogued as rs782344783, COSV64964638; called by muse, mutect2, varscan2
- TET2 | c.2289C>T p.P763= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54409281; called by muse, mutect2, varscan2
- TMC4 | c.1437C>A p.V479= (on ENST00000617472 / NM_001145303.3; = p.V473= on NM_144686.4) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55827038, COSV55827568; called by muse, mutect2, varscan2
- TMC7 | c.891G>A p.R297= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV58583235; called by muse, mutect2, varscan2
- TP53BP2 | c.1476G>A p.R492= (on ENST00000343537 / NM_001031685.3; = p.R363= on NM_005426.2) | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100636583; called by muse, mutect2, varscan2
- TRIM29 | c.693G>A p.T231= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs774273938, COSV59280128; called by muse, mutect2, varscan2
- TRIOBP | c.2628G>A p.E876= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as COSV60376802, COSV60381837; called by muse, mutect2, varscan2
- TRPC7 | c.2349C>T p.I783= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV61457377; called by mutect2, varscan2
- WIZ | c.5481C>T p.F1827= (on ENST00000673675 / NM_001371589.1; = p.F732= on NM_021241.3) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs747864855, COSV54607165; called by muse, mutect2, varscan2
- WNT7A | c.231C>T p.F77= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs772049042, COSV53197745; called by muse, mutect2, varscan2
- ZGLP1 | c.372G>A p.Q124= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV58532917; called by muse, mutect2, varscan2
- DKC1 | c.771+136C>T | Intron (SNP) | VAF 18/95 reads (19%) | catalogued as COSV101059873; called by muse, mutect2, varscan2
- DSG4 | c.-2G>A | 5'UTR (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100355169; called by muse, mutect2, varscan2
- FRMPD2B | n.1304C>T | RNA (SNP) | VAF 9/10 reads (90%) | catalogued as rs1168350542; called by mutect2, varscan2
- KIR3DL2 | chr19:54847764 G>A | 5'Flank (SNP) | VAF 40/207 reads (19%) | called by muse, varscan2
- RORA | c.196+63637A>G | Intron (SNP) | VAF 21/65 reads (32%) | catalogued as rs918589907, COSV99832508; called by muse, mutect2, varscan2
